Somatic mutation profile of tumor specimen C3L-01560-01 (aliquot CPT0086030009) from CPTAC case C3L-01560, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 54.1 years (19,752 days).
Specimen C3L-01560-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae356ae8-017e-4640-84a0-e0f847336f51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01560-31 (Blood Derived Normal), aliquot CPT0086720001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90314b60-1376-4d48-a4c3-d76c3dea44e8

The open-access MAF lists 51 somatic variants for this specimen: 36 protein-altering or splice-affecting, 7 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 7, Intron 5, Frame Shift Del 3, 5'UTR 1, Nonstop Mutation 1, Splice Region 1, Frame Shift Ins 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHB2 | c.2356G>A p.G786R (on ENST00000400191 / NM_001309193.2; = p.G787R on NM_004442.7) | Missense Mutation (SNP) | VAF 72/406 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138551214, CM082613; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- VHL | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 130/348 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CD962176, CM056724, CM114396, COSV56542752, COSV56558534; called by muse, mutect2, varscan2
- ADAMTS20 | c.1340G>C p.S447T | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV67137552; called by muse, mutect2, varscan2
- CD209 | c.1195C>A p.P399T | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.093); catalogued as rs752457226, COSV52657534; called by muse, mutect2, varscan2
- CEP250 | c.3122A>G p.Q1041R | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV100698742; called by muse, mutect2, varscan2
- KRT16 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 127/528 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as rs148632325; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1163A>C p.D388A | Missense Mutation (SNP) | VAF 73/311 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100365185; called by muse, mutect2, varscan2
- TTC21A | c.3031C>A p.P1011T | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs1035848593; called by muse, mutect2, varscan2
- ZSCAN10 | c.28C>T p.L10F (on ENST00000252463; = p.L65F on NM_032805.3) | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as rs111927493; called by muse, mutect2, varscan2
- AP3D1 | c.3292G>A p.E1098K | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CD180 | c.442C>A p.L148M | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CFAP43 | c.2694T>C p.C898= | Splice Region (SNP) | VAF 16/89 reads (18%) | called by muse, mutect2, varscan2
- CHD1L | c.204_217del p.L69Gfs*21 | Frame Shift Del (DEL) | VAF 18/153 reads (12%) | called by mutect2, pindel
- CHI3L2 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DNAJC5B | c.203A>G p.H68R | Missense Mutation (SNP) | VAF 115/508 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- EFTUD2 | c.2156A>T p.Q719L | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- EHHADH | c.1226A>G p.N409S | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELFN1 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAT3 | c.5203T>A p.S1735T | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HYDIN | c.6325G>A p.A2109T | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL34 | c.10G>T p.G4C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- INSYN1 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IVNS1ABP | c.167A>G p.Y56C | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- KIAA1109 | c.10282T>C p.C3428R | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MPP1 | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- MYH10 | c.5460G>T p.E1820D | Missense Mutation (SNP) | VAF 37/222 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OR8B8 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PARP8 | c.1044del p.R349Gfs*6 | Frame Shift Del (DEL) | VAF 60/310 reads (19%) | called by mutect2, pindel, varscan2
- PRAMEF2 | c.580del p.Y194Ifs*6 | Frame Shift Del (DEL) | VAF 44/229 reads (19%) | called by mutect2, pindel, varscan2
- RFC5 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC39A13 | c.620T>A p.L207H | Missense Mutation (SNP) | VAF 95/466 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TRIP6 | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USP39 | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- ZFHX2 | c.4260dup p.E1421* | Frame Shift Ins (INS) | VAF 26/106 reads (25%) | called by mutect2, pindel, varscan2
- ZFP69B | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); called by muse, mutect2
- ZNF395 | c.1541G>T p.*514Lext*46 | Nonstop Mutation (SNP) | VAF 93/381 reads (24%) | called by muse, mutect2, varscan2
- AMIGO1 | c.343C>T p.L115= | Silent (SNP) | VAF 62/302 reads (21%) | called by muse, mutect2, varscan2
- DUOXA2 | c.246C>T p.N82= | Silent (SNP) | VAF 67/340 reads (20%) | called by muse, mutect2, varscan2
- ITGA3 | c.1387C>A p.R463= | Silent (SNP) | VAF 32/143 reads (22%) | catalogued as CM155718, COSV50338735; called by muse, mutect2, varscan2
- PTPRN | c.1845G>A p.L615= | Silent (SNP) | VAF 44/377 reads (12%) | called by muse, mutect2, varscan2
- RNF112 | c.1098G>A p.R366= | Silent (SNP) | VAF 42/183 reads (23%) | catalogued as rs780912506; called by muse, mutect2, varscan2
- SPESP1 | c.9C>T p.P3= | Silent (SNP) | VAF 43/238 reads (18%) | catalogued as COSV52993576; called by muse, mutect2, varscan2
- TNC | c.3159G>T p.L1053= | Silent (SNP) | VAF 75/260 reads (29%) | called by muse, mutect2, varscan2
- ABTB1 | c.-48C>T | 5'UTR (SNP) | VAF 49/202 reads (24%) | called by muse, mutect2, varscan2
- AC073621.1 | n.535G>A | RNA (SNP) | VAF 16/87 reads (18%) | catalogued as rs761883960; called by muse, mutect2, varscan2
- COMMD6 | c.54+228G>C | Intron (SNP) | VAF 32/274 reads (12%) | called by muse, mutect2, varscan2
- FBXL18 | c.1782-4405G>A | Intron (SNP) | VAF 54/255 reads (21%) | catalogued as rs1233118791; called by muse, mutect2, varscan2
- LTBP3 | c.2893+11G>C | Intron (SNP) | VAF 32/145 reads (22%) | called by muse, mutect2, varscan2
- MRPS22 | c.-142-17152del | Intron (DEL) | VAF 69/288 reads (24%) | called by mutect2, pindel, varscan2
- RAB11FIP5 | c.432-116G>C | Intron (SNP) | VAF 38/168 reads (23%) | called by muse, mutect2
- ZNF414 | c.*9G>A | 3'UTR (SNP) | VAF 15/95 reads (16%) | called by muse, mutect2, varscan2
